CDDP_EAGLE case CDDP-ABKE — CDDP_EAGLE-1: CDDP Integrative Analysis of Lung Adenocarcinoma (Phase 2)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Adenomas and Adenocarcinomas; Primary site: Bronchus and lung. Index date: not stated by GDC for this case (day counts are relative to an unstated reference).
https://portal.gdc.cancer.gov/cases/cd54c6fd-3fa8-443b-9ddc-53e29a953ef6

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Age at index: 62 years; Year of birth: 1942; Vital status: Dead; Days to death: 1,518 days (4.2 years); Year of death: 2008; Cause of death: Cancer Related.

Diagnoses (1)
1. Adenocarcinoma with mixed subtypes: ICD-O-3 morphology code: 8255/3; ICD-10 code: C34.9; Tissue or organ of origin: Upper lobe, lung; Site of resection or biopsy: Lung, NOS; Laterality: Left; Age at diagnosis: 62 years; Year of diagnosis: 2004; Days to diagnosis: 0 days; Method of diagnosis: Surgical Resection; AJCC staging edition: 7th; AJCC pathologic T: T1b; AJCC pathologic N: N0; AJCC pathologic M: M0; AJCC pathologic stage: Stage IA; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Days to last follow up: 1,518 days (4.2 years).
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS.
   Recorded as not given: Radiation Therapy, NOS.

Exposures
- Exposure type: Tobacco; Pack years smoked: 14; Cigarettes per day: 0; Exposure duration years: 28.

Biospecimens (2 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample CDDP-ABKE-NB1-A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Preservation method: Snap Frozen.
- Sample CDDP-ABKE-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Snap Frozen.
  Slide CDDP-ABKE-TTP1-A-1-0-S1: Section location: Top; Percent tumor cells: 72; Percent tumor nuclei: 90; Percent normal cells: 2; Percent necrosis: 3; Percent stromal cells: 23; Percent lymphocyte infiltration: 4; Percent monocyte infiltration: 1; Percent neutrophil infiltration: 0.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Protocol status: Completed; Submitted tumor site: Lung; Histologic diagnosis: Lung Adenocarcinoma Mixed Subtype; Cause of death: Submitted Malignancy and/or related tumor event; Height cm at diagnosis: 170 cm; Weight kg at diagnosis: 70 kg; History neoadjuvant treatment: No; Tobacco smoking history indicator: 4; Tobacco smoking year started: 1961; Tobacco smoking year stopped: 1989; KRAS gene analysis indicator: No; EGFR mutation status: No; Eml4 alk translocation status: No; Pulmonary function test indicator: Yes; Treatment outcome first course: Partial Response; Lost to follow-up: No; New tumor event diagnosis indicator: Yes.
- Followup history list, Followup history 1: Tumor status: Never Tumor Free.
- Primary pathology: Lymph nodes examined: Yes; Method initial path diagnosis: Other Surgical Resection (Please Specify).
- Anatomic neoplasm subdivision list: Anatomic organ subdivision: Upper lobe.
- New tumor event 1: Days from index date to new tumor event diagnosis: 756; New tumor event type: Metastatic; New tumor event site other: Bilateral Lungs.
- New tumor event 2: Days from index date to new tumor event diagnosis: 1288; New tumor event type: Metastatic; New tumor event site: Bone.
